Somatic mutation profile of tumor specimen C3L-03748-04 (aliquot CPT0217060006) from CPTAC case C3L-03748, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.0 years (23,735 days).
Specimen C3L-03748-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a100c7ab-8f06-4159-a6fd-44eddf86069d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03748-31 (Blood Derived Normal), aliquot CPT0218000002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b38b3cd4-2298-41d4-9d55-686007ffb942

The open-access MAF lists 90 somatic variants for this specimen: 62 protein-altering or splice-affecting, 19 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Nonsense Mutation 4, Intron 4, 3'UTR 2, 5'UTR 2, Splice Site 2, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.2146G>C p.G716R | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886161, CS961518; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADH4 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs766470523; called by muse, mutect2, varscan2
- ANO1 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs187484921; called by muse, mutect2, varscan2
- AQP9 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs755358483, COSV99582746; called by muse, mutect2, varscan2
- ATP2A3 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 162/583 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373369387; called by muse, mutect2, varscan2
- CT47B1 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 342/949 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.247); catalogued as rs748670528, COSV100988953; called by muse, mutect2, varscan2
- EDARADD | c.392C>T p.P131L (on ENST00000334232 / NM_145861.4; = p.P121L on NM_080738.4) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1005957166, COSV62063155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F2RL3 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 113/243 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs747353327, COSV99935409; called by muse, mutect2, varscan2
- FBLN1 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 23/458 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as rs780525917; called by muse, mutect2
- FOXS1 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs377266974; called by muse, mutect2, varscan2
- GABRA6 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs377498858; called by muse, mutect2, varscan2
- IL13RA2 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 44/124 reads (35%) | catalogued as rs782379686, COSV99683119; called by muse, mutect2, varscan2
- LMNTD2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs765247683, COSV54242782; called by muse, mutect2, varscan2
- LY9 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs199601456, COSV54433623; called by muse, mutect2, varscan2
- MXRA5 | c.5354C>T p.P1785L | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs957998828; called by muse, mutect2, varscan2
- NALCN | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51958793; called by muse, mutect2
- POU6F2 | c.1403-2A>G p.X468_splice | Splice Site (SNP) | VAF 56/209 reads (27%) | catalogued as rs1227585387; called by muse, mutect2, varscan2
- SMC1B | c.2356G>A p.V786M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs774065033, COSV62528872; called by muse, mutect2, varscan2
- SPATA31A1 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 112/391 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.409); catalogued as rs1364577801; called by muse, mutect2, varscan2
- STAG2 | c.1751A>G p.K584R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54350249; called by muse, mutect2, varscan2
- SUPT6H | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs140234142; called by muse, mutect2
- SVEP1 | c.3506C>T p.A1169V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.825); catalogued as rs765955604, COSV57029599; called by muse, mutect2, varscan2
- TES | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs750864842, COSV64042800; called by muse, mutect2, varscan2
- TEX15 | c.5740G>A p.E1914K (on ENST00000256246; = p.E2297K on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1043021013; called by muse, mutect2, varscan2
- TOR2A | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1357803191; called by muse, mutect2, varscan2
- TTBK1 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs779375420, COSV99443379; called by muse, varscan2
- TTN | c.65129G>A p.R21710Q (on ENST00000591111; = p.R14286Q on NM_003319.4) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | PolyPhen benign (0.015); catalogued as rs376046188, COSV60178349; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs554953025; called by muse, mutect2, varscan2
- URB1 | c.5809G>A p.V1937I | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs764258602, COSV60567464; called by muse, mutect2, varscan2
- USH2A | c.12094G>A p.G4032R | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs908265742, CM1514190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UTS2R | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 170/588 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760796306; called by muse, mutect2, varscan2
- ZFP42 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as rs201496236, COSV58816371, COSV58818564; called by muse, mutect2, varscan2
- APOB | c.13313G>A p.S4438N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10A | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ATP4A | c.1886G>A p.G629D | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- BTBD18 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- C4orf54 | c.3620C>T p.A1207V | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- COX8C | c.126G>A p.A42= | Splice Region (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- DNHD1 | c.10615T>A p.L3539M | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DRP2 | c.252T>G p.N84K | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- FAM71B | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- GJA10 | c.1224C>A p.D408E | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GOLM2 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GPR182 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- HMCN1 | c.15593A>G p.E5198G | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- KLHL12 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT9 | c.1143G>T p.E381D | Missense Mutation (SNP) | VAF 66/453 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- LILRB3 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED13L | c.1124A>T p.H375L | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OGT | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 45/149 reads (30%) | called by muse, mutect2, varscan2
- PCDHB2 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 141/526 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- POLR2A | c.2349+1G>C p.X783_splice | Splice Site (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- PPEF1 | c.1251G>T p.K417N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RRP15 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- SCAF8 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- SECISBP2L | c.2718A>C p.K906N (on ENST00000559471 / NM_001193489.2; = p.K861N on NM_014701.4) | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC9A7 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SRPK3 | c.494_502del p.E165_L167del | In Frame Del (DEL) | VAF 40/136 reads (29%) | called by mutect2, varscan2
- TAS2R4 | c.370A>T p.N124Y | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- TCL1B | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TGM2 | c.1951A>G p.R651G | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- TRMT10B | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ADH1C | c.90A>G p.A30= | Silent (SNP) | VAF 21/152 reads (14%) | called by muse, mutect2, varscan2
- ADRA1D | c.633C>T p.R211= | Silent (SNP) | VAF 107/354 reads (30%) | called by muse, mutect2, varscan2
- AP3B2 | c.300C>T p.Y100= | Silent (SNP) | VAF 69/230 reads (30%) | catalogued as rs781365751, COSV55606781; called by muse, mutect2, varscan2
- BRD1 | c.1563G>A p.K521= | Silent (SNP) | VAF 77/280 reads (28%) | called by muse, mutect2, varscan2
- C6orf120 | c.405C>T p.Y135= | Silent (SNP) | VAF 201/653 reads (31%) | called by muse, mutect2, varscan2
- CELA3B | c.258C>T p.G86= | Silent (SNP) | VAF 82/257 reads (32%) | catalogued as rs777462398, COSV61403467; called by muse, mutect2, varscan2
- CRISPLD1 | c.312G>A p.L104= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as rs201227381, COSV51548331; called by muse, mutect2, varscan2
- DOK6 | c.801G>A p.A267= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as rs376128954, COSV66926015; called by muse, mutect2, varscan2
- EPHA6 | c.2316A>G p.L772= (on ENST00000389672 / NM_001080448.3; = p.L164= on NM_173655.4) | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- FGFBP1 | c.174C>T p.G58= | Silent (SNP) | VAF 47/148 reads (32%) | catalogued as COSV99469194; called by muse, mutect2, varscan2
- GAK | c.2673C>T p.G891= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as rs753898629, COSV58503631; called by muse, mutect2, varscan2
- INHBA | c.546G>A p.P182= | Silent (SNP) | VAF 87/367 reads (24%) | catalogued as rs141733287, COSV54222714; called by muse, mutect2, varscan2
- KRTAP13-4 | c.114C>A p.P38= | Silent (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- NKX2-4 | c.606C>T p.Y202= | Silent (SNP) | VAF 187/635 reads (29%) | catalogued as rs1020428813; called by muse, mutect2, varscan2
- PIWIL3 | c.141G>A p.P47= | Silent (SNP) | VAF 75/248 reads (30%) | catalogued as rs527502722; called by muse, mutect2, varscan2
- PLEKHB2 | c.483C>T p.Y161= (on ENST00000409279; = p.Y160= on NM_017958.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 69/251 reads (27%) | catalogued as rs753839914, COSV99301762; called by muse, mutect2, varscan2
- PPP1R17 | c.267C>T p.Y89= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs141215798; called by muse, mutect2, varscan2
- SLC16A5 | c.1065C>T p.D355= | Silent (SNP) | VAF 18/268 reads (7%) | catalogued as rs760358306; called by muse, mutect2
- SNRPG | c.201C>T p.I67= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV52476311; called by muse, mutect2, varscan2
- CHCHD3 | c.369+1217C>T | Intron (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2
- GCSAML | c.-17C>T | 5'UTR (SNP) | VAF 36/106 reads (34%) | catalogued as rs763443749, COSV100825986, COSV63577061; called by muse, mutect2, varscan2
- KLRD1 | c.-22C>T | 5'UTR (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100282182; called by muse, mutect2, varscan2
- KRT6B | c.*39C>T | 3'UTR (SNP) | VAF 26/58 reads (45%) | catalogued as rs776365127; called by muse, mutect2
- MGAM | c.4619-8718G>A | Intron (SNP) | VAF 61/829 reads (7%) | catalogued as rs768649204; called by muse, mutect2
- PRRT2 | c.1013-18C>T | Intron (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- SLC35A3 | c.*533C>A | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- STXBP2 | c.578+14C>A | Intron (SNP) | VAF 108/220 reads (49%) | catalogued as rs770924561; called by muse, mutect2, varscan2
- TTC3P1 | n.4707A>T | RNA (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
